CPTAC case C3L-01427 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0841a5fd-d084-4a33-abd5-4c43e4d3b8d1

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Dead; Days to death: 1 day; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 74.1 years (27,062 days); Year of diagnosis: 2018; Days to last known disease status: 1 day; Progression or recurrence: no; Days to last follow up: 1 day.

Follow-up (1 entry)
- Days to follow up: 1 day; Karnofsky performance status: 0.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Biospecimens (5 samples)
- Samples C3L-01427-50, C3L-01427-51, C3L-01427-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-01427-54, C3L-01427-56 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
